Somatic mutation profile of tumor specimen TCGA-CM-5341-01A (aliquot TCGA-CM-5341-01A-01D-1408-10) from TCGA case TCGA-CM-5341, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 82.6 years (30,163 days).
Specimen TCGA-CM-5341-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d685998-21d8-4d79-9391-6008cc624b02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-5341-10A (Blood Derived Normal), aliquot TCGA-CM-5341-10A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b284ae0-070b-4fc1-b7c3-9084f24a8844

The open-access MAF lists 166 somatic variants for this specimen: 130 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 32, Nonsense Mutation 11, Frame Shift Del 5, Splice Site 3, Intron 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 18/30 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC093525.2 | c.1067A>G p.H356R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | PolyPhen possibly damaging (0.475); catalogued as COSV53549655, COSV53550676; called by muse, mutect2, varscan2
- ADAMTS20 | c.3451A>G p.K1151E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101166368; called by muse, mutect2
- ADD2 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs201022450; called by muse, mutect2, varscan2
- AEBP1 | c.2113C>G p.L705V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1479557677, COSV56255547; called by muse, mutect2, varscan2
- AOC3 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as rs758238458, COSV57732549; called by muse, mutect2, varscan2
- AP000471.1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV52448827; called by muse, mutect2, varscan2
- APAF1 | c.2365A>T p.N789Y (on ENST00000551964 / NM_181861.2; = p.N778Y on NM_001160.3) | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV59661741; called by muse, mutect2, varscan2
- ARAP2 | c.567C>G p.H189Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.021); catalogued as COSV58282627; called by muse, mutect2, varscan2
- ARMC3 | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.659); catalogued as COSV53057249; called by muse, mutect2, varscan2
- ATF6B | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.696); catalogued as COSV64351298, COSV64351765; called by muse, mutect2, varscan2
- ATG3 | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51925872; called by muse, mutect2, varscan2
- C3 | c.2340G>C p.E780D | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV55571192, COSV99837104; called by muse, mutect2, varscan2
- CCDC87 | c.1203G>T p.M401I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100040115; called by mutect2, varscan2
- CCT4 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66701023; called by muse, mutect2, varscan2
- CD14 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs879447782, COSV57369887; called by muse, mutect2, varscan2
- CDH6 | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as rs771395680, COSV54063694; called by muse, mutect2, varscan2
- CELSR1 | c.8551A>T p.K2851* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV53083739; called by muse, mutect2, varscan2
- CENPB | c.1312del p.E438Kfs*43 | Frame Shift Del (DEL) | VAF 21/113 reads (19%) | catalogued as rs748211874; called by mutect2, pindel, varscan2
- CEP152 | c.3764G>C p.C1255S (on ENST00000380950 / NM_001194998.2; = p.C1199S on NM_014985.4) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV57856712, COSV57859760; called by muse, mutect2, varscan2
- CEP152 | c.2504C>G p.A835G | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV57856724; called by muse, mutect2, varscan2
- CFAP70 | c.2914C>G p.L972V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV60281013, COSV60281206; called by muse, mutect2, varscan2
- COL11A1 | c.4672A>C p.T1558P | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62173271; called by muse, mutect2, varscan2
- CRYBG3 | c.7807G>A p.G2603S | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99477329; called by muse, mutect2, varscan2
- CTNNA2 | c.1940A>C p.Y647S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.138); catalogued as COSV100561671; called by muse, mutect2, varscan2
- DAPP1 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.428); catalogued as rs752528304, COSV56449792; called by mutect2, varscan2
- DCLK1 | c.506C>G p.A169G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.044); catalogued as COSV99712509; called by muse, mutect2, varscan2
- DIP2C | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV55146394; called by muse, mutect2, varscan2
- DISP1 | c.1306T>C p.F436L | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52654746; called by muse, mutect2, varscan2
- DMRTB1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs370607830; called by muse, mutect2, varscan2
- DNAH11 | c.9038C>T p.A3013V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs553655709, COSV60940381; called by muse, mutect2, varscan2
- DNAJC12 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs200719110, COSV56546864; called by muse, mutect2, varscan2
- EML5 | c.3023C>A p.P1008H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61341941; called by muse, mutect2, varscan2
- EP400 | c.2201C>T p.T734M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs146717913; called by muse, mutect2, varscan2
- FAM102A | c.848G>A p.R283Q (on ENST00000373095 / NM_001035254.3; = p.R141Q on NM_203305.2) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as rs200989232, COSV55947376; called by muse, mutect2, varscan2
- FAT3 | c.12377C>T p.P4126L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.352); catalogued as COSV53076930; called by muse, mutect2, varscan2
- FCGBP | c.5921C>T p.T1974M | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs538992262; called by muse, mutect2, varscan2
- FOXI2 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV59094132; called by muse, mutect2, varscan2
- FTHL17 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV63266312; called by muse, mutect2, varscan2
- FYN | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs144813746; called by muse, mutect2, varscan2
- GABRD | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs771493470, COSV66079867; called by muse, mutect2, varscan2
- GAK | c.3385G>A p.A1129T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771331071, COSV58502837; called by muse, mutect2, varscan2
- GARNL3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1008332449, COSV59223838; called by muse, mutect2, varscan2
- GLI1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs149185944; called by muse, mutect2, varscan2
- GON4L | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV55186974; called by muse, mutect2, varscan2
- GRSF1 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV54654560; called by muse, mutect2, varscan2
- HADHB | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 36/93 reads (39%) | catalogued as rs534616210, CM031204, COSV58544605; called by muse, mutect2, varscan2
- HCN1 | c.2438C>A p.A813D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); catalogued as rs777158203, COSV57494324; called by muse, mutect2, varscan2
- HELZ2 | c.4048G>T p.A1350S (on ENST00000467148 / NM_001037335.2; = p.A781S on NM_033405.3) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.571); catalogued as rs376896320, COSV71295400; called by mutect2, varscan2
- HRNR | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV64254333, COSV64260136; called by muse, mutect2, varscan2
- IL24 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs144126009; called by muse, mutect2, varscan2
- IPO11 | c.2431A>C p.N811H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV100320159, COSV100321260; called by muse, mutect2, varscan2
- ISG20L2 | c.655C>G p.P219A | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.61); catalogued as rs1234543475, COSV100494079; called by muse, mutect2
- ITGA4 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs745388020, COSV51997913; called by muse, mutect2, varscan2
- JPH2 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65903890; called by muse, mutect2
- KDM3B | c.1447T>G p.L483V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.967); catalogued as COSV58688092; called by muse, mutect2, varscan2
- KIF17 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as rs747916325, COSV56115777; called by muse, mutect2, varscan2
- KLHDC1 | c.941T>C p.V314A | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs749753363, COSV63778388; called by muse, mutect2, varscan2
- LAMA2 | c.6574-1G>C p.X2192_splice | Splice Site (SNP) | VAF 7/106 reads (7%) | catalogued as COSV101370724; called by muse, mutect2
- LRP1 | c.10345+1G>A p.X3449_splice | Splice Site (SNP) | VAF 5/50 reads (10%) | catalogued as COSV54502336; called by mutect2, varscan2
- LRP1B | c.13291C>T p.P4431S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.996); catalogued as COSV67187416; called by muse, mutect2, varscan2
- LRP2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs186568676, COSV99787995; called by muse, mutect2, varscan2
- MAGEE2 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV64897282; called by muse, mutect2, varscan2
- MED1 | c.1873C>G p.P625A | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.991); catalogued as COSV100328063; called by muse, mutect2, varscan2
- MORC3 | c.877A>G p.K293E | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.297); catalogued as COSV68687747; called by muse, mutect2, varscan2
- MOS | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.765); catalogued as COSV61335946; called by muse, mutect2, varscan2
- MPZL3 | c.5A>T p.Q2L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV54048362; called by muse, mutect2, varscan2
- MRPS9 | c.1174A>C p.T392P | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51518117; called by muse, mutect2, varscan2
- MUSK | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs769211968, COSV51895728; called by muse, mutect2, varscan2
- MYO18B | c.6028G>C p.A2010P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV100124598; called by muse, mutect2, varscan2
- MYO7A | c.3718C>T p.R1240W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371374104, CM071017; called by muse, mutect2, varscan2
- NCAM2 | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1169950337, COSV53055743, COSV53099064; called by muse, mutect2, varscan2
- NCL | c.824A>T p.E275V | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV59544876; called by muse, mutect2, varscan2
- NDUFAF5 | c.340A>T p.K114* | Nonsense Mutation (SNP) | VAF 34/131 reads (26%) | catalogued as COSV65246497; called by muse, mutect2, varscan2
- NEPRO | c.342-1G>C p.X114_splice | Splice Site (SNP) | VAF 16/146 reads (11%) | catalogued as COSV58722580; called by muse, mutect2, varscan2
- NFASC | c.1345C>T p.R449W (on ENST00000339876 / NM_001378329.1; = p.R460W on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as rs184631101; called by muse, mutect2, varscan2
- NR1H4 | c.1099C>T p.R367* (on ENST00000551379 / NM_001206993.2; = p.R353* on NM_005123.4) | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV51849489; called by muse, mutect2, varscan2
- NUB1 | c.791A>T p.H264L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63425844; called by muse, mutect2, varscan2
- OCA2 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.572); catalogued as rs552418165, COSV62339253, COSV62347333; called by muse, mutect2
- OR4A15 | c.406C>A p.R136S | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.314); catalogued as rs746232440, COSV59033682, COSV59035771; called by muse, mutect2, varscan2
- P2RY6 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs374484031; called by muse, mutect2, varscan2
- PAPPA2 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1158834771, COSV62773157; called by muse, mutect2, varscan2
- PARVB | c.288G>T p.W96C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58684026; called by muse, mutect2, varscan2
- PAXIP1 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1211359069, COSV66897964; called by muse, mutect2, varscan2
- PCDHA12 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.005); catalogued as COSV56478452; called by muse, mutect2, varscan2
- PCDHA13 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56478461; called by muse, mutect2, varscan2
- PCDHA2 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs547468977, COSV65364688; called by muse, mutect2, varscan2
- PCDHB14 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV53386575; called by muse, mutect2, varscan2
- PCDHB3 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV50564230; called by muse, mutect2, varscan2
- PCDHGA12 | c.2619G>A p.M873I | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as rs1457918073, COSV52743445; called by muse, mutect2, varscan2
- PLEKHA6 | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV55330086, COSV55330361; called by muse, mutect2, varscan2
- PLIN5 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.048); catalogued as rs747789366, COSV67850361; called by muse, mutect2, varscan2
- POLD2 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs752936314, COSV56261524, COSV99789006; called by muse, mutect2, varscan2
- POTEF | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as rs550374458, COSV62539753; called by muse, mutect2, varscan2
- PRDM9 | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs747527740, COSV57002648; called by muse, mutect2, varscan2
- R3HDM4 | c.649T>A p.F217I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV64292724; called by mutect2, varscan2
- RAD23A | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57118051; called by muse, mutect2, varscan2
- RFT1 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV56248104; called by muse, mutect2, varscan2
- RIMBP2 | c.2932C>A p.L978I | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55464774; called by muse, mutect2
- RPE65 | c.1489C>A p.Q497K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV52013263; called by muse, mutect2, varscan2
- SEC23B | c.2090T>A p.I697N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52718451; called by muse, mutect2, varscan2
- SEMA3G | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs767520734, COSV51593523, COSV51593792; called by muse, mutect2, varscan2
- SEMA7A | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs373206524; called by muse, mutect2, varscan2
- SH3TC2 | c.2592C>G p.N864K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV60460817; called by muse, mutect2, varscan2
- SLCO4C1 | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs754562682, COSV60512840; called by muse, mutect2, varscan2
- SPECC1 | c.1388T>A p.I463N | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV54952866; called by muse, mutect2, varscan2
- SRRM1 | c.2566A>G p.T856A | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV60475287; called by muse, mutect2, varscan2
- STK4 | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV65669433; called by muse, mutect2, varscan2
- SYNE1 | c.22603C>A p.L7535M (on ENST00000367255 / NM_182961.4; = p.L7464M on NM_033071.3) | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV55035204; called by muse, mutect2, varscan2
- TAF5 | c.934G>C p.D312H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60856345; called by muse, mutect2, varscan2
- TAS1R2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.231); catalogued as rs139111014, COSV64743564; called by muse, mutect2, varscan2
- TBC1D19 | c.997T>A p.F333I | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV53514366; called by muse, mutect2
- TBC1D19 | c.999T>G p.F333L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.991); catalogued as COSV53514374; called by muse, mutect2
- TCF25 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs766899076, COSV54524450; called by muse, mutect2, varscan2
- TMEM117 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56894667; called by muse, mutect2, varscan2
- TMOD1 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs766826917, COSV52244829; called by muse, mutect2, varscan2
- TRAM1 | c.750T>G p.F250L | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV51596683; called by muse, mutect2, varscan2
- TRAM1L1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs1319817952, COSV60291249; called by muse, mutect2, varscan2
- TTC24 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs1207034073, COSV63998536; called by muse, mutect2
- TTC6 | c.1418T>A p.L473H (on ENST00000267368; = p.L1839H on NM_001310135.3) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57446452; called by muse, mutect2, varscan2
- TTF1 | c.836del p.K279Rfs*144 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | catalogued as rs746659855; called by mutect2, varscan2
- VCPIP1 | c.2645C>G p.S882C | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV60046058; called by muse, mutect2
- WIPF2 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60272258; called by muse, mutect2, varscan2
- ZC3H13 | c.2203C>T p.R735* | Nonsense Mutation (SNP) | VAF 72/173 reads (42%) | catalogued as COSV54447888; called by muse, mutect2, varscan2
- ZC3H13 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 20/121 reads (17%) | catalogued as rs1466115407, COSV54447918; called by muse, mutect2, varscan2
- ADAMTS8 | c.619del p.A207Pfs*38 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- SBF2 | c.2390_2391del p.Y797* | Frame Shift Del (DEL) | VAF 6/82 reads (7%) | called by mutect2, pindel
- TAF1L | c.1026_1054delinsGATAAAT p.S343Ifs*38 | Frame Shift Del (DEL) | VAF 42/214 reads (20%) | called by pindel, varscan2*
- ADAMTS8 | c.2550C>T p.A850= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs760788962, COSV57291275, COSV57296777; called by muse, mutect2, varscan2
- C1QA | c.453C>T p.F151= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV65889260; called by muse, mutect2, varscan2
- COL12A1 | c.5238C>A p.I1746= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV59389707; called by muse, mutect2, varscan2
- CRAT | c.1605C>T p.P535= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs920445276; called by muse, mutect2, varscan2
- DNAH11 | c.2826G>A p.P942= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs368794820, COSV100178129; called by muse, mutect2, varscan2
- DNAH11 | c.9279C>T p.S3093= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs200160729; called by muse, mutect2, varscan2
- EPHX3 | c.387G>T p.V129= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV55654627; called by muse, mutect2, varscan2
- FHOD1 | c.1197G>A p.L399= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV50758635; called by muse, mutect2, varscan2
- GLIS3 | c.897G>T p.P299= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs748660259, COSV60924121; called by muse, mutect2
- HCK | c.828C>T p.V276= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV52940274; called by muse, mutect2, varscan2
- HCN2 | c.795C>T p.T265= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs372286860, COSV99241331, COSV99242155; called by mutect2, varscan2
- HMCN1 | c.8205T>C p.A2735= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV54878062; called by muse, mutect2, varscan2
- IFIT1B | c.1152C>T p.Y384= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs756778499; called by muse, mutect2
- IGSF9B | c.1147C>A p.R383= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV58063992, COSV58067017; called by muse, mutect2, varscan2
- ITGA4 | c.450T>C p.N150= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV51997926, COSV99275717; called by muse, mutect2, varscan2
- KRT83 | c.309C>T p.N103= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as rs752860418, COSV53338391; called by muse, mutect2, varscan2
- LDHD | c.1332C>G p.V444= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV55580058; called by muse, mutect2, varscan2
- NLRC3 | c.234G>A p.P78= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs747375398, COSV57087188; called by muse, mutect2, varscan2
- PIDD1 | c.1926C>T p.A642= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV57192309; called by muse, mutect2, varscan2
- POSTN | c.1467C>T p.R489= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as rs1234284132, COSV65711689; called by muse, mutect2, varscan2
- PPRC1 | c.825C>T p.P275= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV53383136, COSV53386445; called by muse, mutect2, varscan2
- PRODH2 | c.306C>T p.G102= (on ENST00000301175; = p.G26= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs755999165, COSV56558350; called by muse, mutect2, varscan2
- PTPRT | c.1236C>T p.Y412= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs376152261, COSV62000894; called by muse, mutect2
- RB1CC1 | c.4755G>A p.V1585= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV50243179; called by muse, mutect2, varscan2
- RSL1D1 | c.1434A>G p.K478= | Silent (SNP) | VAF 28/312 reads (9%) | catalogued as COSV63077414; called by muse, mutect2
- SLC37A1 | c.411C>T p.S137= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs573347357, COSV61401312; called by muse, mutect2, varscan2
- SOX5 | c.1308G>A p.A436= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as rs780771208, COSV58618786; called by muse, mutect2, varscan2
- SPEG | c.5110C>T p.L1704= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100405277; called by muse, mutect2, varscan2
- TAGLN2 | c.564C>T p.G188= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs147762227; called by muse, mutect2, varscan2
- TMED9 | c.636C>T p.L212= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV50352646; called by muse, mutect2, varscan2
- ZFYVE9 | c.1248C>T p.N416= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs749890553, COSV55090219; called by muse, mutect2, varscan2
- ZNF382 | c.1221G>A p.P407= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs780590866, COSV53086148; called by muse, mutect2, varscan2
- AMDHD2 | c.970+28G>A | Intron (SNP) | VAF 9/60 reads (15%) | catalogued as rs1354635736, COSV99566061; called by muse, mutect2, varscan2
- ANKS1B | c.3067-6758C>T | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as rs752206048, COSV59115257; called by muse, mutect2, varscan2
- C1QTNF2 | c.-1G>C | 5'UTR (SNP) | VAF 7/15 reads (47%) | catalogued as COSV101220886; called by muse, mutect2, varscan2
- MIR17 | n.84C>G | RNA (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
